Somatic mutation profile of tumor specimen TCGA-56-A4BY-01A (aliquot TCGA-56-A4BY-01A-11D-A24D-08) from TCGA case TCGA-56-A4BY, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,445 days).
Specimen TCGA-56-A4BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 887b05b0-dfdd-4d70-9b17-cf70484315c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A4BY-10A (Blood Derived Normal), aliquot TCGA-56-A4BY-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8e0cd7-a519-4f81-ac4f-4ad7743e7a93

The open-access MAF lists 161 somatic variants for this specimen: 120 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 38, Nonsense Mutation 11, Frame Shift Ins 3, Frame Shift Del 3, Splice Region 2, Splice Site 2, Nonstop Mutation 1, Translation Start Site 1, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPS1 | c.2407C>A p.R803S | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201716417, CM098027, CM114352, CM114353, COSV51810496, COSV51817776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.239C>A p.T80K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553487947, COSV67960012, COSV67960020, COSV67960088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 55/102 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3907A>G p.R1303G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100383183; called by muse, mutect2, varscan2
- ADGRL3 | c.1069C>T p.Q357* (on ENST00000506720 / NM_001322402.2; = p.Q289* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV101547217, COSV72270438; called by muse, mutect2, varscan2
- ALMS1 | c.12419C>T p.S4140L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV100042723; called by muse, mutect2, varscan2
- ANKRD35 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100841753; called by muse, mutect2, varscan2
- ANKRD44 | c.1274A>G p.Q425R | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99985193; called by muse, mutect2, varscan2
- ANO9 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100241005; called by muse, mutect2, varscan2
- APBA2 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101258179; called by muse, mutect2, varscan2
- ARG2 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV99373772; called by muse, mutect2, varscan2
- ARHGAP32 | c.5287C>T p.Q1763* (on ENST00000310343 / NM_001378025.1; = p.Q1414* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100088051; called by muse, mutect2, varscan2
- ARMC10 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.776); catalogued as COSV100085771; called by muse, mutect2, varscan2
- ASB4 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100367195; called by muse, mutect2
- ATP10A | c.2336G>T p.C779F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100791316; called by muse, mutect2
- ATP2B1 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99665825; called by muse, mutect2
- B3GAT1 | c.308C>G p.T103R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100437971, COSV56996800; called by muse, mutect2, varscan2
- B3GAT2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100017077; called by muse, mutect2, varscan2
- BROX | c.548A>C p.Y183S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100572231; called by muse, mutect2, varscan2
- C12orf40 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100210199; called by muse, mutect2, varscan2
- CCDC74B | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775950124, COSV100134520; called by muse, mutect2, varscan2
- CCDC81 | c.1219-2A>G p.X407_splice (on ENST00000445632 / NM_001156474.2; = p.X317_splice on NM_021827.4) | Splice Site (SNP) | VAF 35/68 reads (51%) | catalogued as rs772946585, COSV99564412; called by muse, mutect2, varscan2
- CD209 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.257); catalogued as COSV99214046; called by muse, mutect2, varscan2
- CDH11 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV51766813; called by muse, mutect2
- CDH20 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV99405638; called by muse, mutect2, varscan2
- CEP192 | c.3415G>T p.D1139Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100381420; called by muse, mutect2, varscan2
- CEP70 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/138 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs146129165; called by muse, mutect2, varscan2
- CHD2 | c.4748C>A p.A1583D | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV101245416; called by muse, mutect2, varscan2
- CLCA4 | c.2249C>A p.P750H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as COSV100991131; called by muse, mutect2, varscan2
- CNGB3 | c.1186A>T p.R396* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100182160; called by muse, mutect2, varscan2
- CNTLN | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99264465; called by muse, mutect2, varscan2
- CPNE3 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV99547741, COSV99547989; called by muse, mutect2, varscan2
- CPNE8 | c.681A>G p.R227= | Splice Region (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100504531; called by muse, mutect2, varscan2
- CSMD3 | c.11072G>A p.G3691E (on ENST00000297405 / NM_001363185.1; = p.G3522E on NM_052900.3) | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV52154527; called by muse, mutect2, varscan2
- CYBB | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101059769; called by muse, mutect2, varscan2
- DCC | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as rs140711456, COSV100500647; called by muse, mutect2, varscan2
- DDX59 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100494576; called by muse, mutect2, varscan2
- DNAH7 | c.8774A>G p.Y2925C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750153406, COSV100415616; called by muse, mutect2, varscan2
- DOCK11 | c.4614T>A p.D1538E | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV99354046; called by muse, mutect2, varscan2
- DUSP11 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99731103; called by muse, mutect2, varscan2
- EGFLAM | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100380374; called by muse, mutect2, varscan2
- ELMOD3 | c.341T>A p.V114E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100226350; called by muse, mutect2, varscan2
- ESPNL | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.485); catalogued as rs773279911, COSV100547833; called by muse, varscan2
- EYS | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100676612; called by muse, mutect2, varscan2
- F5 | c.5397G>A p.M1799I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100889136; called by muse, mutect2, varscan2
- FAM228A | c.514A>T p.K172* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99722575; called by muse, mutect2, varscan2
- FAM91A1 | c.1078+2T>G p.X360_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100593634; called by muse, mutect2, varscan2
- FREM1 | c.4323G>C p.Q1441H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101084771; called by muse, mutect2, varscan2
- GDPD2 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 15/18 reads (83%) | catalogued as COSV100978642; called by muse, mutect2, varscan2
- GFRAL | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100475289; called by muse, mutect2, varscan2
- GLI2 | c.3211A>T p.T1071S (on ENST00000361492 / NM_001374353.1; = p.T1088S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100082595, COSV100083407; called by muse, mutect2, varscan2
- GRIA1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV53596833, COSV99600379; called by muse, mutect2, varscan2
- ITIH6 | c.2288T>G p.V763G | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99513423; called by muse, mutect2, varscan2
- KRTAP10-12 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100554069; called by muse, mutect2, varscan2
- LRGUK | c.2251T>A p.W751R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.798); catalogued as COSV99604305; called by muse, mutect2, varscan2
- MAP1B | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.194); catalogued as COSV99702501; called by muse, mutect2
- MCM2 | c.1615G>T p.V539L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99413203; called by muse, mutect2, varscan2
- MFSD6 | c.2107T>C p.Y703H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.93); catalogued as COSV55621454, COSV99855217; called by muse, mutect2, varscan2
- MIDEAS | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99678947; called by muse, mutect2
- MTNR1A | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs769593513, COSV100208220; called by mutect2, varscan2
- MUC16 | c.24310G>T p.G8104C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV67480746, COSV67487395; called by muse, mutect2, varscan2
- NAF1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99919187; called by muse, mutect2, varscan2
- NEB | c.17965G>A p.E5989K | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.992); catalogued as COSV99424167; called by muse, mutect2, varscan2
- NLRP4 | c.2537G>A p.C846Y | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016453; called by muse, mutect2, varscan2
- NMBR | c.988A>G p.S330G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99237312; called by muse, mutect2, varscan2
- NOX4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV99630811, COSV99631740; called by muse, mutect2
- OLFM3 | c.1241C>A p.A414D (on ENST00000338858 / NM_001288821.1; = p.A394D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100129629; called by muse, mutect2, varscan2
- OR4A15 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1392127114, COSV100124161; called by muse, mutect2, varscan2
- OR4S2 | c.213C>G p.Y71* | Nonsense Mutation (SNP) | VAF 59/172 reads (34%) | catalogued as COSV100412565, COSV100412687, COSV56746668; called by muse, mutect2, varscan2
- PCDH9 | c.3320G>T p.G1107V (on ENST00000377865 / NM_203487.3; = p.G1073V on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100121350; called by muse, mutect2, varscan2
- PCDHB4 | c.1211C>G p.T404R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1206472876, COSV99522259; called by muse, mutect2, varscan2
- PDPK1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as rs142153837; called by muse, mutect2, varscan2
- PHLDB1 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1555104224, COSV100616590, COSV61877064; called by muse, mutect2, varscan2
- PLPPR1 | c.44del p.P15Rfs*41 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | catalogued as COSV66458694; called by mutect2, pindel, varscan2
- PNPLA5 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV99336666; called by muse, mutect2, varscan2
- PRKCE | c.1394A>G p.K465R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100078276; called by muse, mutect2, varscan2
- PSME4 | c.2946G>T p.V982= | Splice Region (SNP) | VAF 47/90 reads (52%) | catalogued as COSV101122535; called by muse, mutect2, varscan2
- PTPRH | c.3213C>G p.F1071L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671103; called by muse, mutect2, varscan2
- PUS7L | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100786552; called by muse, mutect2, varscan2
- RASGRF2 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99429499; called by muse, mutect2, varscan2
- REC8 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV100269086; called by muse, mutect2, varscan2
- RIPOR3 | c.2173G>C p.G725R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs756926679, COSV99246617; called by muse, mutect2, varscan2
- SAMD3 | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100148272; called by muse, mutect2, varscan2
- SCAF11 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1390824984, COSV101014409; called by muse, mutect2, varscan2
- SCN5A | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.818); catalogued as COSV100028402, COSV60067676; called by muse, mutect2
- SEC14L3 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs369059111, COSV53178710, COSV53180485; called by muse, mutect2, varscan2
- SERPINA10 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56228844; called by muse, mutect2, varscan2
- SLC43A3 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV100725213; called by muse, mutect2, varscan2
- SLFN13 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV53193141, COSV99540065; called by muse, mutect2, varscan2
- SLITRK3 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53848430, COSV99579409; called by muse, mutect2, varscan2
- SNRK | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs575732643, COSV99939152; called by muse, mutect2, varscan2
- TAF1L | c.4027G>T p.V1343F | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV99644829; called by muse, mutect2, varscan2
- TBC1D9 | c.3607A>G p.T1203A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV101464354; called by muse, mutect2, varscan2
- TBR1 | c.897G>C p.W299C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271482; called by muse, mutect2, varscan2
- TGIF2LX | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99383412; called by muse, mutect2, varscan2
- TKTL2 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); catalogued as COSV99761463; called by muse, mutect2, varscan2
- TLR4 | c.1766G>T p.S589I (on ENST00000355622 / NM_138554.5; = p.S549I on NM_003266.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100842781, COSV62922730; called by muse, mutect2, varscan2
- TMC2 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100727663; called by muse, mutect2, varscan2
- TMEM215 | c.444C>G p.S148R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100713208; called by muse, mutect2, varscan2
- TMPRSS15 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV99518176; called by muse, mutect2, varscan2
- TRAF3 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV100693626; called by muse, mutect2, varscan2
- TRHDE | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99669032; called by muse, mutect2, varscan2
- TRPM2 | c.2386G>T p.V796L | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV100308926, COSV100309518; called by muse, mutect2, varscan2
- UNC13C | c.3946G>A p.V1316M | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs777734668, COSV99518549; called by muse, mutect2, varscan2
- VPS13D | c.13165T>C p.*4389Rext*25 | Nonstop Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99167047; called by muse, mutect2, varscan2
- ZNF260 | c.252A>T p.K84N | Missense Mutation (SNP) | VAF 89/176 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101591061; called by muse, mutect2, varscan2
- ZNF527 | c.1771T>C p.F591L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100648741; called by muse, mutect2, varscan2
- ZNF540 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100143818; called by muse, mutect2
- ZNF578 | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV101405062; called by muse, mutect2
- ZNF600 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100593011; called by muse, mutect2, varscan2
- ZNF783 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as COSV100954259; called by muse, mutect2, varscan2
- ABCA6 | c.3101del p.G1034Afs*30 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- CEP170 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CHD4 | c.5609dup p.V1871Sfs*11 (on ENST00000357008 / NM_001363606.2; = p.V1881Sfs*11 on NM_001273.5) | Frame Shift Ins (INS) | VAF 35/310 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA0895 | c.579del p.N194Mfs*3 (on ENST00000297063 / NM_001100425.2; = p.N143Mfs*3 on NM_015314.3) | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- TBC1D14 | c.286dup p.I96Nfs*21 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | called by mutect2, varscan2
- TBC1D14 | c.291dup p.E98Rfs*19 | Frame Shift Ins (INS) | VAF 25/138 reads (18%) | called by mutect2*, pindel, varscan2*
- TPTE | c.1425T>A p.D475E (on ENST00000618007 / NM_199261.4; = p.D457E on NM_199259.4) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ADAMTS12 | c.3933C>G p.G1311= | Silent (SNP) | VAF 60/116 reads (52%) | catalogued as COSV100711108; called by muse, mutect2, varscan2
- AKAP9 | c.5724A>G p.T1908= (on ENST00000359028; = p.T1876= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs780509776, COSV100662513; called by muse, mutect2, varscan2
- ATP6V1E2 | c.24G>T p.V8= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as COSV100120756; called by muse, mutect2, varscan2
- BCL2L1 | c.678G>T p.L226= (on ENST00000307677 / NM_001317919.2; = p.L163= on NM_001191.4) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100304740, COSV56969021; called by muse, mutect2, varscan2
- CADM2 | c.630C>A p.L210= (on ENST00000407528 / NM_001167674.2; = p.L212= on NM_153184.4) | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV101056327, COSV67382080, COSV67411355; called by muse, mutect2, varscan2
- DLEC1 | c.3315G>A p.A1105= | Silent (SNP) | VAF 61/114 reads (54%) | catalogued as rs747286665, COSV57300862, COSV57304849; called by muse, mutect2, varscan2
- ESYT2 | c.1080G>A p.V360= (on ENST00000613624; = p.V284= on NM_020728.3) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs778679256, COSV99276827; called by muse, mutect2, varscan2
- F13B | c.426T>A p.S142= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100803319; called by muse, mutect2, varscan2
- FOXN3 | c.876G>C p.R292= (on ENST00000261302; = p.R270= on NM_005197.4) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99726651; called by muse, mutect2
- GJA1 | c.804C>T p.F268= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99247054; called by muse, mutect2, varscan2
- H4C7 | c.216C>A p.T72= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99769125; called by muse, mutect2, varscan2
- HCN1 | c.1510C>A p.R504= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV100300654, COSV57498398; called by muse, mutect2, varscan2
- HPSE2 | c.1350C>A p.R450= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100985936; called by muse, mutect2, varscan2
- IGSF9B | c.1992C>A p.I664= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100317839; called by muse, mutect2, varscan2
- MAP1A | c.684C>T p.G228= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100288756; called by muse, mutect2, varscan2
- MAP3K21 | c.2181C>T p.T727= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs201566282, COSV100786111, COSV64043047; called by muse, mutect2, varscan2
- MMP3 | c.831G>C p.T277= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV55405782, COSV55407008; called by muse, mutect2, varscan2
- MYO3B | c.2661C>T p.A887= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100510525; called by muse, mutect2, varscan2
- NAALAD2 | c.2136T>A p.R712= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV100428515; called by muse, mutect2, varscan2
- NLRP4 | c.816G>A p.E272= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100016448; called by muse, mutect2, varscan2
- NPR1 | c.1785G>T p.L595= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100902035; called by muse, mutect2, varscan2
- OR5J2 | c.792C>T p.S264= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100399065; called by muse, mutect2, varscan2
- OR6C75 | c.339G>T p.L113= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100595359; called by muse, mutect2, varscan2
- OR8J3 | c.894T>C p.N298= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100040869; called by muse, mutect2, varscan2
- PACS1 | c.2145C>T p.N715= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs150214972; called by muse, mutect2, varscan2
- PCDH18 | c.780G>T p.P260= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1439330843, COSV100787365, COSV61272428; called by muse, mutect2, varscan2
- PRRC2C | c.4608A>G p.P1536= (on ENST00000367742; = p.P1534= on NM_015172.4) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100145419; called by muse, mutect2, varscan2
- PUM1 | c.1923A>T p.A641= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99928227; called by muse, mutect2, varscan2
- RET | c.342C>A p.R114= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100393794, COSV60686640; called by muse, mutect2, varscan2
- SARDH | c.1164C>A p.P388= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100898807; called by muse, mutect2
- SCN2A | c.4296T>G p.V1432= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99332066; called by muse, mutect2, varscan2
- SIPA1L3 | c.567G>A p.G189= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs770360644, COSV55912592; called by muse, mutect2
- SPEN | c.7956C>T p.S2652= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs755358455, COSV101005273; called by muse, mutect2, varscan2
- SUPT6H | c.4623C>G p.A1541= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as COSV99972748; called by muse, mutect2, varscan2
- TBX15 | c.1407G>A p.L469= (on ENST00000369429 / NM_001330677.2; = p.L363= on NM_152380.3) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99254299; called by muse, mutect2, varscan2
- TGFB3 | c.879G>A p.Q293= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV53168989, COSV99472569, COSV99472726; called by muse, mutect2, varscan2
- ZNF761 | c.213A>T p.A71= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV100483403; called by muse, mutect2, varscan2
- ZP4 | c.1287G>T p.V429= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100850697; called by muse, mutect2, varscan2
- ABCA3 | c.-132G>T | 5'UTR (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100068655; called by muse, mutect2, varscan2
- GK5 | c.816+210T>C | Intron (SNP) | VAF 17/24 reads (71%) | catalogued as COSV101242231; called by muse, mutect2, varscan2
- TMEM99 | n.517C>T | RNA (SNP) | VAF 40/147 reads (27%) | catalogued as rs374835718; called by muse, mutect2, varscan2
